CCDI case PBCLDG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/655efc12-30c9-4d0a-ae8e-d7d934cf410a

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 4.0 years (1,456 days).

Biospecimens (3 samples)
- Sample 0DUETN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUEU8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUEUC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
